PECGS case C083-000033 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/1e61f1c2-a95e-4273-a8ee-dbc532109fcd

Demographics
Sex at birth: male; Age at index: 59 years; Year of birth: 1963; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Age at diagnosis: 58.9 years (21,513 days); AJCC clinical stage: Stage IIA; Progression or recurrence: no.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 5.25.

Biospecimens (2 samples)
- Sample C083-000033_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000033_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
